CCDI case PBBKAF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/20041cf0-3f7d-4654-a534-77d5f2e7f58b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.1 years (2,590 days).

Biospecimens (3 samples)
- Sample 0DAGOV: Tissue type: Normal; Specimen type: Solid Tissue.
- Sample 0DAGOZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAGP6: Tissue type: Tumor; Specimen type: Solid Tissue.
